FM case AD15555 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Transitional Cell Papillomas and Carcinomas.
https://portal.gdc.cancer.gov/cases/8c7a079d-4c56-43be-b37a-72ec39e3776a

Male, 74.6 years: Urothelial carcinoma, NOS (ICD-O-3 8120/3); specimen biopsied or resected from the lymph node. Tumor nuclei on the sequenced sample's slide: 33% (pathologist estimate recorded by GDC). Sample type: Tumor.
